Somatic mutation profile of tumor specimen TCGA-HT-7610-01A (aliquot TCGA-HT-7610-01A-21D-2086-08) from TCGA case TCGA-HT-7610, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 25.9 years (9,447 days).
Specimen TCGA-HT-7610-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3ee6bf-b1cf-41d0-870a-b499d49dc39f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7610-10A (Blood Derived Normal), aliquot TCGA-HT-7610-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8f0b377-107f-4fcd-a9b6-23f1104fc0a3

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 29/58 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCG5 | c.1628T>C p.L543P | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs199862542, COSV53209439; called by muse, mutect2, varscan2
- ADGRL3 | c.2680C>T p.R894C (on ENST00000506720 / NM_001322402.2; = p.R826C on NM_015236.6) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs370521883; called by muse, mutect2, varscan2
- ATRX | c.4809+2T>G p.X1603_splice | Splice Site (SNP) | VAF 36/107 reads (34%) | catalogued as COSV64871295; called by muse, mutect2, varscan2
- BCOR | c.2909C>T p.A970V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771757019, COSV60699508; called by muse, mutect2, varscan2
- F5 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs770011773, HM971410, COSV63120371; called by mutect2, varscan2
- PAPOLA | c.2190T>G p.N730K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV53478937; called by muse, mutect2, varscan2
- SENP3 | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53441891; called by muse, mutect2, varscan2
- STAG2 | c.1733A>T p.Y578F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV54350709; called by muse, mutect2, varscan2
- TP53 | c.688A>C p.T230P | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52678462, COSV52750166, COSV52783174, COSV52787639; called by muse, mutect2, varscan2
- TRIP12 | c.2458C>T p.R820* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as rs1195592039, COSV52259058; called by muse, mutect2, varscan2
- ADGRA2 | c.2835C>T p.C945= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs200170236, COSV55102594; called by mutect2, varscan2
- ASTE1 | c.2010G>A p.E670= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV53907544; called by muse, mutect2, varscan2
- HBZ | c.18T>C p.T6= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs769761534, COSV53316448; called by muse, mutect2, varscan2
- KRT27 | c.705C>T p.C235= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV56970698; called by muse, mutect2, varscan2
